FM case AD8100 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Germ Cell Neoplasms; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/39d93d50-907b-4393-be80-b2f2ac7544ed

Male, 37.0 years: Germ cell tumor, NOS (ICD-O-3 9064/3) of the testis; metastasis biopsied or resected from the brain. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
